Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CV-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: R frontal

Diagnosis: anaplastic oligoastrocytoma (grade III WHO)

Name of Pathologist:

ICD-O-3
Oligoastrocytoma, anaplastic 9382/3
C6CF
Site Brain, supratentorial NOS C71.0
path B Brain, frontal lobe C71.1
JW 5/16/13

Histology Discrepancy		✓

Source: NCI Genomic Data Commons file 489e2582-3270-40d4-936a-14201d2d4310 (TCGA-QH-A6CV.DC5685CF-74DF-45C6-B530-831FC33228C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).